Somatic mutation profile of tumor specimen TCGA-IK-8125-01A (aliquot TCGA-IK-8125-01A-11D-2253-08) from TCGA case TCGA-IK-8125, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 62.3 years (22,745 days).
Specimen TCGA-IK-8125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48bfa6c8-ed88-4ec7-b3ea-2e2942cf7a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IK-8125-10A (Blood Derived Normal), aliquot TCGA-IK-8125-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dab76aa1-657a-4ac6-9af1-9f98e7b241af

The open-access MAF lists 55 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TPM1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs104894505, CM014116, COSV104385526, COSV51259749; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs767763176, COSV52526829; called by muse, mutect2, varscan2
- CHRM3 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55080229, COSV55103433, COSV55104375; called by muse, mutect2
- COL18A1 | c.3202A>G p.K1068E (on ENST00000359759 / NM_130444.3; = p.K833E on NM_030582.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV60586482; called by muse, mutect2, varscan2
- CRIP3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV51482745; called by muse, mutect2
- CRYBG3 | c.6559C>T p.Q2187* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV51709472; called by muse, mutect2, varscan2
- DIXDC1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472099566, COSV67742227; called by muse, mutect2, varscan2
- ENAM | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV68535196; called by muse, mutect2, varscan2
- FAT1 | c.11860G>A p.G3954S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71671934; called by mutect2, varscan2
- FLNB | c.2576-1G>A p.X859_splice | Splice Site (SNP) | VAF 79/208 reads (38%) | catalogued as COSV55870236; called by muse, mutect2, varscan2
- FTSJ1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50025559; called by muse, mutect2, varscan2
- KIAA1217 | c.4789A>T p.K1597* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV56812373; called by muse, mutect2, varscan2
- KPRP | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765434263, COSV64220950; called by muse, mutect2, varscan2
- LHFPL1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767818059, COSV64332935; called by muse, mutect2, varscan2
- MAP3K12 | c.1260-2A>T p.X420_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV57231198; called by muse, mutect2, varscan2
- NAF1 | c.1211A>G p.Q404R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV56803247; called by muse, mutect2, varscan2
- NEO1 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1212821730, COSV56067470; called by muse, mutect2, varscan2
- NGEF | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV50914416; called by muse, mutect2, varscan2
- NOTCH1 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53028453, COSV53035640; called by muse, mutect2, varscan2
- NSDHL | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as rs199567542, COSV64743135; called by muse, mutect2, varscan2
- PLEC | c.8668G>A p.A2890T (on ENST00000322810 / NM_201380.4; = p.A2780T on NM_000445.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1454146801, COSV59603503; called by muse, mutect2, varscan2
- PPP2R5D | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1000620573, COSV57839098; called by muse, mutect2, varscan2
- PRRC2C | c.4408C>G p.P1470A (on ENST00000367742; = p.P1468A on NM_015172.4) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58900918; called by muse, mutect2
- RUNX1T1 | c.1627G>C p.D543H (on ENST00000265814 / NM_001198628.1; = p.D516H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56137534; called by muse, mutect2, varscan2
- SLIT1 | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV56582396; called by muse, mutect2, varscan2
- SMAD2 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV50992923; called by muse, mutect2
- SPPL2A | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.026); catalogued as COSV55939830; called by muse, mutect2, varscan2
- TBX5 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs200354838, COSV59858482; called by muse, mutect2, varscan2
- TEAD2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as rs775244653, COSV60543467; called by muse, mutect2, varscan2
- THSD7B | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as COSV55654487; called by muse, mutect2, varscan2
- TRPM1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56630471; called by muse, mutect2, varscan2
- TTC12 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs373487103; called by muse, mutect2, varscan2
- TTN | c.8450G>C p.S2817T (on ENST00000591111; = p.S2771T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | PolyPhen possibly damaging (0.879); catalogued as COSV59888158; called by muse, mutect2
- U2AF2 | c.666G>C p.Q222H | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58272390; called by muse, mutect2
- ZNF292 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60535567; called by muse, mutect2, varscan2
- ZNF878 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs769849405, COSV72155900; called by muse, mutect2, varscan2
- CIC | c.3804del p.K1268Nfs*34 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- GLB1L2 | c.664_689del p.R222Ffs*54 | Frame Shift Del (DEL) | VAF 56/243 reads (23%) | called by mutect2, pindel, varscan2
- HFM1 | c.2866dup p.I956Nfs*10 | Frame Shift Ins (INS) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- PSMD1 | c.1831_1833del p.N611del | In Frame Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- ALDH1A1 | c.1374C>T p.G458= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs755799729, COSV99921209; called by mutect2, varscan2
- BPIFB3 | c.1287C>T p.S429= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV64956776; called by muse, mutect2, varscan2
- DAPK3 | c.330G>A p.S110= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as rs749765274, COSV56662183; called by muse, mutect2, varscan2
- FPGS | c.855C>G p.A285= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV64675332; called by muse, mutect2, varscan2
- GNE | c.195C>T p.T65= (on ENST00000396594 / NM_001128227.3; = p.T34= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs147290887, COSV64951248; called by muse, mutect2, varscan2
- HELLS | c.1941G>A p.G647= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV53294423; called by muse, mutect2, varscan2
- NOTCH3 | c.1341C>T p.L447= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV54626462; called by muse, mutect2, varscan2
- NOTCH4 | c.4425C>T p.R1475= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV66678727; called by muse, mutect2, varscan2
- NOTCH4 | c.414G>A p.S138= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as rs201835213, COSV66678729; called by muse, mutect2
- PARVB | c.126G>A p.Q42= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as rs1290390175, COSV58683880; called by muse, mutect2, varscan2
- PNPLA1 | c.603C>A p.P201= (on ENST00000394571 / NM_001374623.1; = p.P106= on NM_173676.2) | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV57232428; called by muse, mutect2, varscan2
- SPINK4 | c.84G>A p.S28= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs745978913, COSV101121895, COSV101121898; called by mutect2, varscan2
- TTBK1 | c.2931G>A p.A977= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs756556063, COSV52488106; called by muse, mutect2, varscan2
- TRIM61 | c.526-2328A>G | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as COSV61418737; called by muse, mutect2
